TCGA case TCGA-4A-A93X — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Mary Bird Perkins Cancer Center - Our Lady of the Lake. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/deace3d5-26fc-44d3-9f39-b5cde2c94152

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 58.4 years (21,348 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC clinical T: T3a; AJCC clinical N: N1; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic T: T3a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 390 days (1.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sunitinib Malate; Days to treatment start: 63 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 4 days; Disease response: With Tumor.
- Days to follow up: 390 days (1.1 years); Disease response: With Tumor.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Molecular and laboratory tests
- Hemoglobin: Low.
- Calcium: Low.
- Leukocytes: Low.
- Platelets: Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 112 kg; Height: 178 cm; BMI: 35.3.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-4A-A93X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 710 mg.
  Slide TCGA-4A-A93X-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 20; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-4A-A93X-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-4A-A93X-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; White cell count: Low; Lymph nodes examined: Yes; Tobacco smoking history indicator: 1; Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: Sutent.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Stable Disease; Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 390 days; disease-specific survival: no event (censored), 390 days; progression-free interval: no event (censored), 390 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-4A-A93X-01A-11D-A36W-01): tumor purity 0.87, ploidy 2.81, whole-genome doublings 1.
